CCDI case PBCIWP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/87faddb3-f791-4cb5-8ef5-72a2c2ce61c6

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Biospecimens (3 samples)
- Sample 0DSWYS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSWZ4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSWZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
